Somatic mutation profile of tumor specimen TCGA-CJ-5684-01A (aliquot TCGA-CJ-5684-01A-11D-1534-10) from TCGA case TCGA-CJ-5684, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.8 years (22,561 days).
Specimen TCGA-CJ-5684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 037ebdfb-ca9a-433c-8a92-e786075906b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5684-11A (Solid Tissue Normal), aliquot TCGA-CJ-5684-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a8e8434-3043-43db-99ac-ec475cb1145b

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, In Frame Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP3 | c.37G>T p.G13* | Nonsense Mutation (SNP) | VAF 183/570 reads (32%) | catalogued as rs570803135, COSV57416871, COSV99962121; called by muse, mutect2, varscan2
- ASXL3 | c.2987C>A p.P996Q | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV52466378; called by muse, mutect2, varscan2
- CYP8B1 | c.1079T>C p.V360A | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60226376; called by muse, mutect2, varscan2
- DNAH2 | c.3053C>T p.S1018L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs559459258, COSV66717494, COSV66719598; called by muse, mutect2, varscan2
- DYRK3 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV65606294; called by muse, mutect2, varscan2
- ESPN | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV64704375; called by muse, mutect2, varscan2
- GRM4 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs371727193; called by muse, mutect2, varscan2
- IL9R | c.177C>A p.N59K | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV54899833; called by muse, mutect2, varscan2
- JHY | c.1697A>T p.Q566L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV57075202; called by muse, mutect2, varscan2
- KASH5 | c.1134G>C p.E378D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV71358017; called by muse, mutect2, varscan2
- KCNC1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs369830206, COSV56394349; called by muse, mutect2, varscan2
- LATS2 | c.2072dup p.H691Qfs*36 | Frame Shift Ins (INS) | VAF 38/160 reads (24%) | catalogued as rs1565942755; called by mutect2, pindel, varscan2
- MMS19 | c.846G>A p.L282= | Splice Region (SNP) | VAF 46/396 reads (12%) | catalogued as COSV59135138; called by muse, mutect2, varscan2
- MYCBP2 | c.3286T>C p.Y1096H (on ENST00000357337; = p.Y1134H on NM_015057.5) | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV62019554; called by muse, mutect2, varscan2
- PBRM1 | c.3553C>T p.R1185* (on ENST00000296302 / NM_001366071.2; = p.R1160* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 76/433 reads (18%) | catalogued as COSV56264314; called by muse, mutect2, varscan2
- PCDH15 | c.2779A>G p.S927G | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1265390601, COSV57312932; called by muse, mutect2, varscan2
- PCDH15 | c.2778T>A p.F926L | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57312956; called by muse, mutect2, varscan2
- PEX26 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as COSV61604443; called by muse, mutect2, varscan2
- SDR16C5 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 120/466 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58126505; called by mutect2, varscan2
- SETD2 | c.4584A>T p.E1528D | Missense Mutation (SNP) | VAF 163/386 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57437860; called by muse, mutect2, varscan2
- SLC12A2 | c.2363+2T>G p.X788_splice | Splice Site (SNP) | VAF 50/227 reads (22%) | catalogued as COSV52471301; called by muse, mutect2, varscan2
- TESC | c.568A>T p.I190F | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV58811948; called by muse, mutect2, varscan2
- THSD7B | c.4543C>A p.P1515T (on ENST00000272643; = p.P1513T on NM_001316349.2) | Missense Mutation (SNP) | VAF 90/834 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55687809; called by muse, mutect2, varscan2
- TXNIP | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs782302261, COSV65219911; called by muse, mutect2
- VIRMA | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 124/421 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV52585137; called by muse, mutect2, varscan2
- WBP2 | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV54663715; called by muse, mutect2, varscan2
- FBXL4 | c.782_785delinsC p.S261_L262delinsT | In Frame Del (DEL) | VAF 87/351 reads (25%) | called by pindel, varscan2*
- USP20 | c.1768_1769insT p.R590Lfs*71 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | called by mutect2, pindel*, varscan2
- E2F7 | c.1458C>A p.L486= | Silent (SNP) | VAF 63/277 reads (23%) | catalogued as COSV59740031; called by muse, mutect2, varscan2
- PIP4K2B | c.552G>T p.L184= | Silent (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
- SCUBE1 | c.1833G>A p.K611= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV62612476; called by muse, mutect2, varscan2
- SERPINA4 | c.64C>T p.L22= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV54069969; called by muse, mutect2, varscan2
- TCHH | c.847C>A p.R283= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs1401241560, COSV64274842; called by muse, mutect2, varscan2
- TEK | c.45C>T p.L15= | Silent (SNP) | VAF 115/1137 reads (10%) | catalogued as COSV66228988; called by muse, mutect2
- TMEM86A | c.69C>T p.C23= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as rs551911585, COSV55010748; called by muse, mutect2, varscan2
- TYW1 | c.1218C>T p.R406= | Silent (SNP) | VAF 243/1222 reads (20%) | catalogued as rs1359685742, COSV62752633; called by muse, mutect2, varscan2
- VWF | c.7131G>A p.P2377= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs745348661, COSV54620612; called by muse, mutect2, varscan2
- CHST8 | c.-2G>A | 5'UTR (SNP) | VAF 16/61 reads (26%) | catalogued as rs572454321, COSV52861829; called by muse, mutect2, varscan2
